Somatic mutation profile of tumor specimen MP2PRT-PATRDW-TMP1-A (aliquot MP2PRT-PATRDW-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PATRDW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.2 years (5,930 days).
Specimen MP2PRT-PATRDW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d84f56af-554a-4e4c-b0f9-1393c7904199.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATRDW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATRDW-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75056ddc-cf77-47a3-b0c6-c9431d6caf02

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 10, Silent 5, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 90/391 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ASXL2 | c.1856T>G p.L619R | Missense Mutation (SNP) | VAF 82/232 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55461006; called by muse, mutect2, varscan2
- CEP78 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 108/507 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776232414, COSV52848273; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMXL1 | c.2801G>A p.R934K | Missense Mutation (SNP) | VAF 39/337 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100224579; called by muse, mutect2, varscan2
- GRIN2B | c.4321C>T p.R1441C | Missense Mutation (SNP) | VAF 127/428 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs773648473, COSV74205585; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNK13 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 100/469 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs772965269, COSV56411318; called by muse, mutect2, varscan2
- NOS1 | c.3385C>T p.R1129C | Missense Mutation (SNP) | VAF 64/254 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs772708191, COSV57607600; called by muse, varscan2
- PRKCQ | c.2098G>A p.G700R | Missense Mutation (SNP) | VAF 56/289 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.117); catalogued as rs748100103, COSV54112707; called by muse, mutect2, varscan2
- SIRPB1 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 102/371 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1320613672; called by muse, mutect2, varscan2
- CREBBP | c.525_526insA p.C176Mfs*5 | Frame Shift Ins (INS) | VAF 120/484 reads (25%) | called by mutect2, pindel, varscan2
- HELLS | c.402A>C p.E134D | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SHLD2 | c.1866dup p.V623Sfs*38 | Frame Shift Ins (INS) | VAF 59/312 reads (19%) | called by mutect2, pindel, varscan2
- IGKV1OR2-108 | chr2:113406871 ins TAGATTTCCCACCCCTCCAGCGCCA | Silent (INS) | VAF 24/174 reads (14%) | called by mutect2, pindel
- LDB2 | c.813C>T p.S271= | Silent (SNP) | VAF 116/539 reads (22%) | catalogued as rs752982483, COSV58770910, COSV58781123; called by muse, mutect2, varscan2
- MECP2 | c.1356C>T p.H452= | Silent (SNP) | VAF 291/396 reads (73%) | called by muse, mutect2, varscan2
- RNF20 | c.2673G>A p.R891= | Silent (SNP) | VAF 52/274 reads (19%) | called by muse, mutect2, varscan2
- TRPM6 | c.2478G>A p.P826= | Silent (SNP) | VAF 121/538 reads (22%) | catalogued as rs375316759; ClinVar: likely benign; called by muse, mutect2, varscan2
